Gene-level copy-number profile of tumor specimen CDDP-ABLE-TTP1-B from CDDP_EAGLE case CDDP-ABLE, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 53 years.
Specimen CDDP-ABLE-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4a18b426-91d3-4f5b-b493-ea6d13ab3c38.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ABLE-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,742 have no estimate.
https://portal.gdc.cancer.gov/files/6263f6aa-1b49-4487-ba3a-8b768d763d91

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 202; copy number 2: 29,223; copy number 3: 16,092; copy number 4: 9,782; copy number 5: 1,955; copy number 6: 681; copy number 7: 581; copy number 8: 36; copy number 9: 148; copy number 10: 28; copy number 11: 48; copy number 12: 93; copy number 17: 2; copy number 18: 6.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:92,456,205–92,482,506, 1 gene (within-gene range 0–2): ASPN.
- chr19:8,721,634–8,732,160, 2 genes: OR2Z1, RPL23AP78.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,576 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–156,385,219, 592 genes, copy number 6–12 (broad region; genes not listed).
- chr1:156,920,632–164,899,296, 254 genes, copy number 5–9 (within-gene range 3–9) (broad region; genes not listed).
- chr2:38,814–41,157,555, 661 genes, copy number 5 (broad region; genes not listed).
- chr3:63,819,299–64,103,131, 13 genes, copy number 6 (within-gene range 4–6): C3orf49, THOC7, THOC7-AS1, ATXN7, SCAANT1, PSMD6-AS2, AC012557.1, PSMD6, PSMD6-AS1, AC012557.2, PRICKLE2-AS1, U3, LINC00994.
- chr3:139,935,185–144,445,844, 75 genes, copy number 6–18 (broad region; genes not listed).
- chr3:148,090,341–150,296,605, 58 genes, copy number 6–12: AC092958.3, AC092958.2, AC025566.1, HNRNPA1P20, LINC02045, LINC02046, AC069410.1, RPL38P1, AGTR1, CPB1, HMGB1P30, AC092979.1, CPA3, AC092979.2, UBQLN4P1, GYG1, HLTF, HLTF-AS1, Y_RNA, MED28P2, HPS3, CP, CPHL1P, AC093001.1, TM4SF18, AC073522.1, TM4SF1, TM4SF1-AS1, AC108751.4, AC108751.2, AC108751.3, FKBP1AP4, AC108751.1, TM4SF4, AC108751.5, WWTR1, RNU6-1098P, WWTR1-IT1, WWTR1-AS1, COMMD2, ANKUB1, RNU6-507P, RNF13, RNU6-720P, NPM1P29, PFN2, AC117395.1, TMEM183B, PPIAP73, HNRNPA1P24, AC117386.2, AC022494.1, LINC01998, RPL32P9, AC117386.1, LINC01213, U2, LINC01214.
- chr3:150,761,937–154,539,309, 59 genes, copy number 8–10 (within-gene range 4–10): SIAH2-AS1, CLRN1-AS1, MINDY4B, AC020636.2, AC020636.1, CLRN1, AC108726.1, MED12L, RNA5SP145, GPR171, P2RY14, SETP11, AC078816.1, GPR87, P2RY13, P2RY12, IGSF10, MRPL42P6, AC117454.1, MIR5186, LINC02066, AADACL2, AADACL2-AS1, AC068647.1, AADACP1, AC068647.2, AADAC, SUCNR1, AC108718.1, MBNL1, MBNL1-AS1, TMEM14EP, Y_RNA, AC026347.1, AC092924.1, ATP5MGP5, P2RY1, HMGN2P13, AC117394.1, AC117394.2, RAP2B, RN7SL300P, AC078788.1, AC078788.2, LINC02006, LINC02877, RNU6-901P, Y_RNA, AC068985.1, U8, RPL21P42, ARHGEF26-AS1, ARHGEF26, DHX36, AC134026.1, AC134026.2, GPR149, DDX50P2, AC092994.1.
- chr3:158,962,235–172,448,456, 167 genes, copy number 6–11 (broad region; genes not listed).
- chr5:18,704,433–24,850,971, 54 genes, copy number 5: LINC02100, UBE2V1P12, AC025768.1, AC114981.1, Metazoa_SRP, AC106744.1, AC106744.2, RPL32P14, HSPD1P15, CDH18, AC093303.1, AC094103.1, CDH18-AS1, LINC02146, LINC02241, AC138938.1, AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1, CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1, C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1, AC010342.1, AC010387.1, Metazoa_SRP, CDH10, AC091885.2, AC091885.1, AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239.
- chr9:42,231,811–42,569,353, 8 genes, copy number 12–17: AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1.
- chr14:34,485,979–35,932,325, 49 genes, copy number 5 (within-gene range 4–5): RPL23AP71, EAPP, AL445363.3, AL445363.1, RNU1-27P, RNU1-28P, AL445363.2, SNX6, RPS19P3, Metazoa_SRP, RNU6-1261P, RPL23AP8, CFL2, RPL12P6, BAZ1A, RNU7-41P, AL121603.2, SRP54-AS1, AL121603.1, IGBP1P1, SRP54, FAM177A1, PPP2R3C, AL049776.1, PRORP, AL121594.1, RPL23AP70, SEPTIN7P1, MRPL57P8, DPRXP3, RPL7AP3, RPL9P3, PSMA6, AL133163.2, AL133163.1, NFKBIA, DNAJC8P1, AL133163.3, RPS3AP4, KRT18P6, INSM2, RALGAPA1, AL137818.1, QRSL1P3, AL162311.3, NUTF2P2, BRMS1L, AL162311.1, AL162311.2.
- chr14:73,462,362–74,360,008, 45 genes, copy number 5 (within-gene range 3–5): AC005280.1, HEATR4, RIOX1, AC005225.1, AC005225.3, ACOT1, NT5CP2, AC005225.2, ACOT2, NT5CP1, AC005225.4, ACOT4, ACOT6, NDUFB8P1, DNAL1, RNU6-240P, AC006146.1, PNMA1, MIDEAS, MIR4505, AC005520.2, LINC02274, AC005520.4, PTGR2, AC005520.1, Y_RNA, AC005520.5, ZNF410, AC005480.1, AC005520.3, Y_RNA, FAM161B, COQ6, ENTPD5, AC005480.2, BBOF1, ALDH6A1, LIN52, RN7SL530P, AC006349.1, VSX2, ABCD4, AC005519.1, VRTN, SUB1P2.
- chr19:28,294,093–28,970,874, 17 genes, copy number 5: AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2.
- chr19:30,219,666–42,295,797, 521 genes, copy number 5–6 (broad region; genes not listed).
- chr20:31,257,664–61,940,617, 722 genes, copy number 5–10 (broad region; genes not listed).
- chr21:8,603,547–8,603,984, 1 gene, copy number 6: RPSAP68.
- chr22:21,103,016–24,927,578, 280 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 202. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
